Surgical pathology report (de-identified scan), TCGA case TCGA-22-5483, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5483-01A (Primary Tumor).

DIAGNOSIS:

Lung, right upper lobe, lung sleeve resection: Invasive grade 4 (of 4) squamous cell carcinoma forming a 3.3 x 3.0 x 3.0 cm endobronchial obstructive mass within the upper lobe main bronchus. Obstructive pneumonia is present in the distal lung parenchyma. A hamartoma (1.0 x 0.8 x 0.7 cm) is also identified. The initial distal margin is negative for tumor, and the initial proximal margin shows focal squamous cell carcinoma in situ. After re-excision, no carcinoma in situ is identified. The separately submitted anterior lateral margin of the right mainstem bronchus is composed of benign soft tissue.

Lung, right upper lobe, anterior basilar, wedge resection: Scar and focal organizing pneumonia.

Bronchus, right mainstem, biopsy: Bronchial mucosa without diagnostic abnormalities.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (7) right lower paratracheal (station 4R) lymph nodes.
- No tumor is identified in multiple (18) subcarinal (station 7) lymph nodes.

Lymph nodes, intrapulmonary/hilar, excision:

- Metastatic carcinoma is identified in multiple (2 of 6) intrapulmonary peribronchial lymph nodes.
- No tumor is identified in a single right hilar (station 10R) lymph node.
- No tumor is identified in multiple (2) interlobar (station 11) lymph nodes.

Source: NCI Genomic Data Commons file a065d195-4ea8-46e0-9ddb-d5afdd59b57a (TCGA-22-5483.45FFB097-F0D9-4850-895E-CE7EBEF84502.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).